Somatic mutation profile of tumor specimen TCGA-DD-A4NK-01A (aliquot TCGA-DD-A4NK-01A-11D-A28X-10) from TCGA case TCGA-DD-A4NK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 80.1 years (29,244 days).
Specimen TCGA-DD-A4NK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca64c514-ad17-458f-8f85-592ea0f7614c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NK-10A (Blood Derived Normal), aliquot TCGA-DD-A4NK-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12da7c15-7654-4014-b765-1632accef831

The open-access MAF lists 87 somatic variants for this specimen: 63 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 23, Splice Site 4, Nonsense Mutation 4, Frame Shift Del 2, In Frame Del 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 54/113 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SRSF2 | c.284_307del p.P95_R102del | In Frame Del (DEL) | VAF 16/54 reads (30%) | hotspot (GDC flag); catalogued as rs766200080; called by mutect2, pindel
- ADAMTSL1 | c.3544G>A p.V1182I | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.426); catalogued as COSV65892231; called by muse, mutect2, varscan2
- ADH1B | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1442109099, COSV59296412; called by muse, mutect2
- ARHGEF17 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.1); catalogued as COSV55231246; called by muse, mutect2, varscan2
- ATRX | c.2531C>T p.T844I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV64876556; called by muse, mutect2, varscan2
- BST1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV53946695; called by muse, mutect2, varscan2
- CDC45 | c.542+1G>T p.X181_splice | Splice Site (SNP) | VAF 43/129 reads (33%) | catalogued as COSV54245417; called by muse, mutect2, varscan2
- CDH1 | c.560A>G p.K187R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.083); catalogued as COSV55732752; called by muse, mutect2, varscan2
- CDK3 | c.482A>G p.H161R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56910954; called by muse, mutect2, varscan2
- CLDN16 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as CM056565, CM124928, COSV53227811; called by muse, mutect2, varscan2
- CTNNA2 | c.1893+1G>T p.X631_splice | Splice Site (SNP) | VAF 41/121 reads (34%) | catalogued as COSV58152765; called by muse, mutect2, varscan2
- CTTN | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 128/326 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1022387444, COSV57232325; called by muse, mutect2, varscan2
- DHX16 | c.1963A>G p.M655V | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs1175528052, COSV64563963; called by muse, varscan2
- DISP1 | c.2306A>G p.K769R | Missense Mutation (SNP) | VAF 108/185 reads (58%) | SIFT tolerated (0.7); PolyPhen benign (0.06); catalogued as COSV52658907; called by muse, mutect2, varscan2
- DSCAM | c.5213C>A p.A1738D | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV68026740; called by muse, mutect2, varscan2
- DUS3L | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1164641504, COSV57831823, COSV57831951; called by muse, mutect2, varscan2
- ECEL1 | c.2161A>G p.I721V | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.122); catalogued as rs779471802, COSV58812270; called by muse, mutect2, varscan2
- ELAC1 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as COSV53996604; called by muse, mutect2, varscan2
- FAT4 | c.10352A>T p.E3451V | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV58684794, COSV58685353; called by muse, mutect2
- FGD3 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); catalogued as COSV100490802, COSV61597337; called by muse, mutect2, varscan2
- FREM2 | c.3368G>A p.G1123D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54834425; called by muse, mutect2, varscan2
- GCAT | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV50649002; called by muse, mutect2, varscan2
- GPR1 | c.995G>A p.C332Y | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV67976821; called by muse, mutect2, varscan2
- GRAP | c.176+1G>A p.X59_splice | Splice Site (SNP) | VAF 12/47 reads (26%) | catalogued as rs1362470152, COSV99408133; called by mutect2, varscan2
- GRIP2 | c.2606G>A p.R869H (on ENST00000619221; = p.R772H on NM_001080423.4) | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs374577398, COSV56123112; called by muse, mutect2, varscan2
- HJV | c.807C>A p.N269K (on ENST00000336751 / NM_213653.4; = p.N156K on NM_145277.5) | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.037); catalogued as COSV60952041; called by muse, mutect2, varscan2
- ICE1 | c.3561T>A p.Y1187* | Nonsense Mutation (SNP) | VAF 28/101 reads (28%) | catalogued as COSV56824956; called by muse, mutect2, varscan2
- IPO13 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.079); catalogued as COSV64894316; called by muse, mutect2, varscan2
- KDM3B | c.2966A>G p.Y989C | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58690744; called by muse, mutect2, varscan2
- LDHAL6B | c.34C>A p.Q12K | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV55687485; called by muse, mutect2
- LRR1 | c.340T>A p.C114S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1265822801, COSV53563524; called by muse, mutect2, varscan2
- MAPT | c.1019T>A p.I340N (on ENST00000262410 / NM_001377265.1; = p.I265N on NM_016835.4) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV52240422; called by muse, mutect2, varscan2
- METTL21C | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57432675, COSV57433951; called by muse, mutect2, varscan2
- MGA | c.1594A>T p.K532* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | catalogued as COSV54953810; called by muse, mutect2
- MUSK | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51878914, COSV51886005; called by muse, mutect2, varscan2
- MYH11 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs375276152; called by muse, mutect2
- NR1H2 | c.530C>A p.S177* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV53800773; called by muse, mutect2, varscan2
- PIBF1 | c.1474C>A p.Q492K | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV58323068; called by muse, mutect2, varscan2
- PLEKHM2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.492); catalogued as rs552932422, COSV65396136; called by muse, mutect2, varscan2
- PLPP1 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV53305117; called by muse, mutect2, varscan2
- POC5 | c.1147A>C p.N383H (on ENST00000428202 / NM_001099271.2; = p.N358H on NM_152408.2) | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as rs1275229292, COSV66842296; called by muse, mutect2, varscan2
- PPP2R5D | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1181904491, COSV57840074; called by muse, mutect2, varscan2
- PTCD1 | c.1646G>A p.R549K | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV52863541; called by muse, mutect2, varscan2
- PTCH1 | c.2059G>T p.V687L | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV59474276; called by muse, mutect2, varscan2
- RBP4 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs367834906; called by muse, mutect2, varscan2
- RP1 | c.4111G>C p.D1371H | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV55116708, COSV55124030; called by muse, mutect2, varscan2
- RTKN2 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65680103, COSV65680212; called by muse, mutect2, varscan2
- SDK1 | c.3650G>A p.R1217H | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1278062937, COSV67359315; called by muse, mutect2, varscan2
- SHPRH | c.533A>T p.E178V | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV51609899; called by muse, mutect2, varscan2
- SIAH1 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 64/171 reads (37%) | catalogued as COSV63210711; called by muse, mutect2, varscan2
- SNX8 | c.1344C>G p.H448Q | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV56126865; called by muse, mutect2, varscan2
- SPATA16 | c.1223T>A p.F408Y | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100651371, COSV63529320; called by muse, mutect2, varscan2
- SPTB | c.3656A>G p.N1219S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs368552247; called by muse, mutect2, varscan2
- STEAP4 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs774129138, COSV57329435; called by muse, mutect2, varscan2
- TMPRSS11E | c.752T>C p.I251T | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs377258215; called by muse, mutect2, varscan2
- ZNF226 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV56196597; called by muse, mutect2, varscan2
- ACVR2A | c.1352_1358del p.M451Sfs*23 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- ALB | c.482+5_482+8del p.X161_splice | Splice Site (DEL) | VAF 12/44 reads (27%) | called by pindel, varscan2
- GAS2L2 | c.121T>A p.W41R | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HIRIP3 | c.738dup p.E247Rfs*6 | Frame Shift Ins (INS) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- TMEM203 | c.376_387del p.Q126_M129del | In Frame Del (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- UBXN1 | c.342del p.E114Dfs*45 | Frame Shift Del (DEL) | VAF 26/69 reads (38%) | called by mutect2, pindel, varscan2
- APBA1 | c.396G>A p.Q132= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV55228033; called by muse, mutect2, varscan2
- ATXN2L | c.2520T>A p.P840= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV57370329; called by muse, mutect2, varscan2
- BHLHE40 | c.1065C>T p.L355= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV56574641; called by muse, mutect2, varscan2
- CNOT10 | c.594A>G p.K198= | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as COSV59392106; called by muse, mutect2, varscan2
- CYP39A1 | c.36G>A p.L12= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as rs767749619, COSV51495697; called by muse, mutect2, varscan2
- EIPR1 | c.477C>T p.I159= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as rs909138274, COSV66129770; called by muse, varscan2
- GNL3L | c.111C>A p.T37= | Silent (SNP) | VAF 92/268 reads (34%) | catalogued as COSV60576335; called by muse, mutect2, varscan2
- GSDME | c.498G>A p.Q166= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as COSV61651680; called by muse, mutect2
- L1CAM | c.813G>T p.T271= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV62827787, COSV62828093; called by muse, mutect2, varscan2
- MACF1 | c.20637T>A p.A6879= (on ENST00000372915; = p.A4924= on NM_012090.5) | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV57121053; called by muse, mutect2
- MAMLD1 | c.2130G>C p.G710= | Silent (SNP) | VAF 122/333 reads (37%) | catalogued as COSV53374865; called by muse, mutect2, varscan2
- MDH1 | c.693C>T p.G231= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as rs542095115, COSV51863482; called by muse, mutect2, varscan2
- NTRK3 | c.2268C>T p.F756= (on ENST00000360948 / NM_001012338.2; = p.F742= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs79813886; called by muse, mutect2, varscan2
- OBSCN | c.17229T>C p.N5743= | Silent (SNP) | VAF 78/254 reads (31%) | catalogued as rs751416415, COSV52774052; called by muse, mutect2, varscan2
- OR1F1 | c.741G>A p.V247= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV58961042; called by muse, mutect2, varscan2
- OR2T6 | c.327G>T p.G109= | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as COSV63215922; called by muse, varscan2
- OR5M8 | c.846T>A p.P282= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV59116815; called by muse, mutect2, varscan2
- RASGRP4 | c.168C>T p.C56= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV53095447; called by muse, mutect2, varscan2
- RSPO1 | c.105G>A p.E35= | Silent (SNP) | VAF 71/182 reads (39%) | catalogued as COSV62974277; called by muse, varscan2
- SOX10 | c.1299G>A p.R433= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV62806591; called by muse, mutect2, varscan2
- VSX2 | c.51G>A p.V17= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV56217312; called by muse, mutect2
- YTHDC2 | c.3984C>T p.S1328= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as COSV50740659; called by muse, mutect2, varscan2
- ZAN | c.924A>T p.S308= | Silent (SNP) | VAF 68/123 reads (55%) | catalogued as COSV61809117; called by muse, mutect2, varscan2
- IGLL5 | chr22:22899638 C>T | 3'Flank (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2
